Gene-level copy-number profile of tumor specimen HTMCP-03-06-02222-01A from CGCI case HTMCP-03-06-02222, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02222-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e0f463f1-dde3-4645-b94a-f9058428eb30.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02222-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,266 have no estimate.
https://portal.gdc.cancer.gov/files/884dbe7a-3e97-494a-b389-ce0aa9100779

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 15; copy number 2: 4,599; copy number 3: 20,948; copy number 4: 16,474; copy number 5: 8,134; copy number 6: 3,366; copy number 7: 2,127; copy number 8: 1,407; copy number 9: 1,279.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,238,286–7,247,571, 2 genes: AF228730.3, OR7E125P.
- chr15:32,441,914–32,536,926, 6 genes (within-gene range 0–2): GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4,813 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,118,534–87,825,952, 20 genes, copy number 7: ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4, PLGLB2, RGPD2, MTATP8P2.
- chr3:98,706,236–101,997,926, 62 genes, copy number 7 (broad region; genes not listed).
- chr3:110,888,384–115,147,288, 86 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:170,864,875–198,123,232, 530 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr5:12,297,399–20,575,873, 114 genes, copy number 7 (broad region; genes not listed).
- chr5:34,158,121–34,373,850, 4 genes, copy number 7: AC139792.1, AC138409.2, AC138409.1, AC138853.1.
- chr5:120,710,698–121,365,314, 7 genes, copy number 7: RNU4-69P, AC114284.1, AC008565.1, AC113352.1, AC008568.1, AC010350.1, AC008568.2.
- chr7:142,500,028–142,793,368, 44 genes, copy number 8: TRBV5-6, TRBV6-8, TRBV7-7, TRBV5-7, TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr7:142,801,041–142,802,748, 1 gene, copy number 8: TRBC2.
- chr8:7,881,392–8,116,949, 16 genes, copy number 7–8: DEFB103A, HSPD1P2, DEFB4A, ZNF705B, DEFB108A, AC130365.1, USP17L8, USP17L3, FAM90A11P, FAM90A24P, FAM90A12P, OR7E96P, AC105233.2, MIR548I3, RPS3AP31, SNRPCP17.
- chr8:41,426,655–43,674,591, 75 genes, copy number 7 (broad region; genes not listed).
- chr8:48,008,415–49,512,180, 23 genes, copy number 7: UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2.
- chr8:51,319,577–52,745,843, 18 genes, copy number 7 (within-gene range 6–7): PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1.
- chr8:53,966,552–54,022,456, 1 gene, copy number 7 (within-gene range 6–7): TCEA1.
- chr8:54,042,989–57,365,444, 60 genes, copy number 7: AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1, AC044836.1, RNU105C, AC027250.1, RN7SL250P, SOX17, AC091076.1, TRMT112P7, RP1, SEC11B, AC090151.1, XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1, TMEM68, RNA5SP265, TGS1, LYN, AC018607.1, SNORA1B, RN7SL798P, RN7SL323P, AC046176.1, RPS20, SNORD54, CERNA3, NPM1P21, MOS, AC107376.1, PLAG1, CHCHD7, AC107952.2, AC107952.1, SDR16C5, SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2, RNU6-13P, BPNT2, RNA5SP266, LINC01606, AC025674.1, AC025674.2, LINC00588, RNU6-596P, AC068075.1.
- chr8:65,526,738–67,746,378, 45 genes, copy number 7–9 (within-gene range 6–9): LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10.
- chr8:68,880,139–75,034,558, 110 genes, copy number 7 (broad region; genes not listed).
- chr8:75,167,704–75,176,656, 1 gene, copy number 7: LINC02886.
- chr8:79,762,371–80,613,826, 30 genes, copy number 8: HEY1, LINC01607, AC036214.1, RNU7-85P, AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P.
- chr8:85,086,615–87,615,219, 50 genes, copy number 7 (within-gene range 6–7): AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1.
- chr8:92,882,984–118,111,826, 356 genes, copy number 7–9 (broad region; genes not listed).
- chr8:120,380,761–122,127,184, 14 genes, copy number 7: MRPL13, MTBP, SNTB1, NCAPGP1, AC104958.1, AC104958.2, AC068413.1, AC011626.1, RPL35AP19, HAS2, HAS2-AS1, LINC02855, AC037486.1, MRPS36P3.
- chr12:273,954–2,004,535, 33 genes, copy number 7 (within-gene range 6–7): AC007406.4, KDM5A, CCDC77, B4GALNT3, NINJ2, AC006205.2, RNU7-103P, AC006205.1, NINJ2-AS1, LINC02455, WNK1, RNU4ATAC16P, AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942, WNT5B, FBXL14, MIR3649, ADIPOR2, AC005183.1, AC005343.4, RPS4XP14, CACNA2D4, AC005343.7, LRTM2, AC005342.2, LINC00940, DCP1B.
- chr14:22,147,995–22,483,069, 39 genes, copy number 9: TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53.
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.
- chr14:34,485,979–106,879,812, 1,670 genes, copy number 7–8 (broad region; genes not listed).
- chr17:35,188,522–35,194,523, 3 genes, copy number 8 (within-gene range 4–8): AC022916.2, AC022916.3, SLC35G3.
- chr20:87,250–26,251,546, 531 genes, copy number 8–9 (broad region; genes not listed).
- chr20:30,278,906–64,327,972, 869 genes, copy number 8–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
